Somatic mutation profile of tumor specimen C3N-00317-04 (aliquot CPT0012280009) from CPTAC case C3N-00317, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.2 years (27,092 days).
Specimen C3N-00317-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b50b2df-469e-4f29-8ff0-a302ea365604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00317-31 (Blood Derived Normal), aliquot CPT0012350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fc4927b-09c7-4ca3-9c96-cc25d321ea66

The open-access MAF lists 117 somatic variants for this specimen: 74 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 26, Frame Shift Del 10, Intron 7, 5'UTR 4, Splice Site 3, RNA 3, 5'Flank 2, Frame Shift Ins 2, Nonstop Mutation 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANGPT4 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs963850145, COSV67921254; called by muse, mutect2, varscan2
- ASZ1 | c.927G>T p.R309S | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV104372636; called by muse, mutect2, varscan2
- ATXN3L | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1555931850; called by muse, mutect2, varscan2
- BAP1 | c.546_547insT p.L183Sfs*10 | Frame Shift Ins (INS) | VAF 48/323 reads (15%) | catalogued as COSV56231810; called by mutect2, pindel, varscan2
- BCAS1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 175/630 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs749019655, COSV65083668, COSV65083914; called by muse, mutect2, varscan2
- GATA3 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 77/426 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60519299, COSV60521231; called by muse, mutect2, varscan2
- GNAT3 | c.701T>A p.L234H | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68068507; called by muse, mutect2, varscan2
- IQUB | c.1603C>G p.Q535E | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs745426564, COSV100227244; called by muse, mutect2, varscan2
- LRRC71 | c.1637A>T p.K546M | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746573089; called by muse, mutect2, varscan2
- NLRP11 | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1373366132; called by muse, mutect2
- PIEZO2 | c.5765C>T p.S1922L | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1343781404; called by muse, mutect2
- POLA1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1317456378; called by muse, varscan2
- POLD1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs372190244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHBDL3 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747341218; called by muse, mutect2, varscan2
- SEPTIN1 | c.446+2T>C p.X149_splice (on ENST00000321367; = p.X102_splice on NM_052838.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 45/154 reads (29%) | catalogued as rs1328616004; called by muse, mutect2, varscan2
- SERPINE2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99296786; called by muse, mutect2, varscan2
- SIGLEC8 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.929); catalogued as rs368238857, COSV100367361; called by muse, mutect2, varscan2
- TBC1D9B | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV62281984; called by muse, mutect2, varscan2
- TRNAU1AP | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs753016583; called by muse, mutect2, varscan2
- USP24 | c.6260C>A p.P2087Q | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.656); catalogued as COSV53775525; called by muse, mutect2, varscan2
- AC092143.1 | c.1284del p.F428Lfs*55 | Frame Shift Del (DEL) | VAF 46/466 reads (10%) | called by mutect2, pindel, varscan2
- ALPK1 | c.148del p.L50* | Frame Shift Del (DEL) | VAF 33/150 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.2695C>A p.H899N | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ARID5A | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ATP13A4 | c.599A>G p.K200R | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, mutect2
- ATXN3 | c.23A>T p.K8I | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- BRD8 | c.1717A>T p.N573Y (on ENST00000254900 / NM_139199.2; = p.N646Y on NM_006696.4) | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C8B | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC106 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC15 | c.1596dup p.L533Sfs*3 | Frame Shift Ins (INS) | VAF 79/500 reads (16%) | called by mutect2, pindel, varscan2
- CHD3 | c.1378C>G p.R460G | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD6 | c.6155_6164del p.E2052Afs*42 | Frame Shift Del (DEL) | VAF 21/190 reads (11%) | called by mutect2, pindel, varscan2
- CNP | c.146G>C p.C49S | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.2929G>A p.A977T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CR1 | c.3555A>C p.K1185N | Missense Mutation (SNP) | VAF 94/471 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CYP26A1 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2
- EMC1 | c.1334G>C p.R445P | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENOSF1 | c.1269_1288del p.D423Efs*37 (on ENST00000340116 / NM_001354066.2; = p.D389Efs*37 on NM_017512.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/214 reads (7%) | called by mutect2, pindel
- FIBCD1 | c.1145A>T p.H382L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- FNDC3A | c.1508del p.L503* (on ENST00000492622 / NM_001079673.2; = p.L447* on NM_014923.5) | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.3325G>A p.V1109M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by mutect2, varscan2
- KIAA0100 | c.3560A>C p.D1187A | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- LAMA2 | c.4655C>T p.A1552V | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MEGF10 | c.916C>A p.R306= | Splice Region (SNP) | VAF 22/104 reads (21%) | called by mutect2, varscan2
- MYOF | c.3841A>T p.I1281F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NCF1 | c.1009del p.R337Afs*39 | Frame Shift Del (DEL) | VAF 69/645 reads (11%) | called by mutect2, pindel, varscan2
- NECAB2 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PARP15 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- PARP15 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PATL1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PHIP | c.3936A>C p.R1312S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PHYKPL | c.916T>G p.Y306D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKD1 | c.4577G>C p.R1526T | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PLAC8 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLEKHB2 | c.929A>G p.*310Wext*? | Nonstop Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- POTEC | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 24/588 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRDM16 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSMD14 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RANBP2 | c.7200A>T p.R2400S | Missense Mutation (SNP) | VAF 56/1218 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- RAPH1 | c.2456del p.F819Sfs*44 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- RGPD4 | c.4275A>T p.R1425S | Missense Mutation (SNP) | VAF 76/654 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- RGS22 | c.3510del p.K1170Nfs*28 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- SART3 | c.2904G>T p.K968N (on ENST00000228284; = p.K950N on NM_014706.4) | Missense Mutation (SNP) | VAF 66/411 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SMAD6 | c.42del p.W14Cfs*50 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- SNRPB2 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- TENT4A | c.1009-1G>A p.X337_splice | Splice Site (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- TNRC18 | c.7353_7357delinsCG p.R2452_R2453delinsG | In Frame Del (DEL) | VAF 14/133 reads (11%) | called by pindel, varscan2*
- TRPC4 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TULP4 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VHL | c.598_599del p.R200Afs*55 | Frame Shift Del (DEL) | VAF 78/410 reads (19%) | called by mutect2, pindel, varscan2
- ZFAT | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF525 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2
- ZNF667 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZSWIM3 | c.632C>G p.T211S | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.4611G>A p.K1537= | Silent (SNP) | VAF 72/577 reads (12%) | called by muse, mutect2, varscan2
- CNNM2 | c.915C>T p.I305= | Silent (SNP) | VAF 98/596 reads (16%) | catalogued as rs371599593, COSV63995689; called by muse, mutect2, varscan2
- CREB5 | c.330G>C p.T110= (on ENST00000357727 / NM_182898.4; = p.T103= on NM_004904.3) | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV63217858; called by muse, varscan2
- CTNNA3 | c.1992A>G p.Q664= | Silent (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- CYP51A1 | c.261A>C p.P87= | Silent (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
- DDR2 | c.978C>T p.D326= | Silent (SNP) | VAF 83/539 reads (15%) | catalogued as rs766364700, COSV63375272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMBT1 | c.156G>A p.S52= | Silent (SNP) | VAF 39/287 reads (14%) | catalogued as rs779781646, COSV57561509; called by muse, mutect2
- GATA3 | c.1098A>T p.R366= | Silent (SNP) | VAF 75/424 reads (18%) | catalogued as rs755075472; called by muse, mutect2, varscan2
- HDAC1 | c.1161C>T p.D387= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs757896216; called by muse, mutect2, varscan2
- HTR1E | c.624G>C p.A208= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV59508553; called by muse, varscan2
- INSM1 | c.582C>T p.A194= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, varscan2
- LDLR | c.2319C>T p.G773= | Silent (SNP) | VAF 51/355 reads (14%) | catalogued as rs377563758; ClinVar: likely benign; called by muse, varscan2
- MAPKAPK3 | c.381C>T p.F127= | Silent (SNP) | VAF 39/213 reads (18%) | catalogued as rs534053112; called by muse, mutect2, varscan2
- MYO15B | c.7731C>G p.S2577= | Silent (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- OR7G3 | c.642C>A p.I214= | Silent (SNP) | VAF 48/246 reads (20%) | catalogued as rs375002810, COSV59640152; called by muse, mutect2, varscan2
- OR9A4 | c.253C>T p.L85= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- PCLO | c.10143T>C p.V3381= | Silent (SNP) | VAF 99/235 reads (42%) | called by muse, mutect2, varscan2
- PIWIL4 | c.1206G>A p.K402= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- PMPCB | c.1443C>A p.R481= | Silent (SNP) | VAF 34/440 reads (8%) | called by muse, mutect2
- RAB11FIP1 | c.123G>A p.A41= | Silent (SNP) | VAF 32/226 reads (14%) | called by muse, mutect2, varscan2
- RPL18A | c.420G>A p.P140= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs772177229; called by muse, mutect2, varscan2
- SP4 | c.1986T>C p.S662= | Silent (SNP) | VAF 77/352 reads (22%) | called by muse, mutect2, varscan2
- TMEM61 | c.132C>T p.T44= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs778412005; called by muse, mutect2, varscan2
- UBP1 | c.960T>C p.Y320= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs1559674373; called by muse, mutect2, varscan2
- UGT1A7 | c.171A>G p.V57= | Silent (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
- YWHAZ | c.90T>A p.T30= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- CD2 | c.-5C>T | 5'UTR (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- CDH15 | chr16:89168558 T>G | 5'Flank (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- CFAP20DC | c.2332+54T>A | Intron (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.3120G>T | RNA (SNP) | VAF 16/397 reads (4%) | called by muse, mutect2
- ERCC6 | c.1397+7607A>G | Intron (SNP) | VAF 42/203 reads (21%) | called by muse, mutect2, varscan2
- FCRLB | c.-6T>C | 5'UTR (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- GPHN | c.-849A>G | 5'UTR (SNP) | VAF 41/162 reads (25%) | called by muse, mutect2, varscan2
- GPHN | c.1314+25T>A | Intron (SNP) | VAF 38/241 reads (16%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.807del | RNA (DEL) | VAF 39/228 reads (17%) | called by mutect2, pindel, varscan2
- LAT | c.163+21C>A | Intron (SNP) | VAF 45/251 reads (18%) | called by muse, mutect2, varscan2
- NEDD4L | c.2427-42G>T | Intron (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- PSIP1 | c.978-1222C>T | Intron (SNP) | VAF 20/144 reads (14%) | catalogued as rs10962042; called by muse, varscan2
- RGPD3 | c.-12G>C | 5'UTR (SNP) | VAF 36/308 reads (12%) | catalogued as COSV100449858; called by muse, mutect2
- SH3KBP1 | c.726+12932G>C | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- SNORD114-24 | n.49C>G | RNA (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- TNNT2 | chr1:201377626 A>G | 5'Flank (SNP) | VAF 50/350 reads (14%) | called by muse, mutect2, varscan2
- XBP1 | c.*263C>T | 3'UTR (SNP) | VAF 22/110 reads (20%) | catalogued as rs751977462, COSV53273909; called by muse, mutect2, varscan2
